Gene-level copy-number profile of tumor specimen TCGA-44-7659-01A from TCGA case TCGA-44-7659, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.4 years (25,730 days).
Specimen TCGA-44-7659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c680112c-3ba1-4588-9390-384a0fbf1313.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-7659-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ca3ce480-30fb-43a7-9c04-7ecbcf74cf71

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,243; copy number 2: 48,229; copy number 3: 5,444; copy number 4: 303; copy number 5: 460; copy number 6: 140.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-7659-01A-11D-2062-01): tumor purity 0.56, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 600 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–7,112,399, 196 genes, copy number 5 (broad region; genes not listed).
- chr5:84,999,812–85,238,074, 6 genes, copy number 5: PPIAP79, AC114928.1, RBBP4P6, AC117522.3, AC117522.2, AC117522.1.
- chr14:29,576,479–30,191,898, 1 gene, copy number 5 (within-gene range 4–5): PRKD1.
- chr14:29,928,445–54,902,826, 397 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
